Somatic mutation profile of tumor specimen TCGA-EM-A3O9-01A (aliquot TCGA-EM-A3O9-01A-11D-A21Z-08) from TCGA case TCGA-EM-A3O9, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 40.5 years (14,783 days).
Specimen TCGA-EM-A3O9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6be7329-7851-482d-a268-336eb7582eb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3O9-10A (Blood Derived Normal), aliquot TCGA-EM-A3O9-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c655d569-ec2a-4228-94a1-f42dea35aa66

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD7 | c.1901A>G p.N634S | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs923690219, COSV58291143; called by muse, mutect2, varscan2
- CDK12 | c.3484G>A p.E1162K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1207423776, COSV71003141; called by muse, mutect2, varscan2
- COL9A1 | c.1585G>A p.G529S | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57886882, COSV57894829; called by muse, mutect2, varscan2
- DNAH6 | c.2231T>A p.I744N | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs1292374558, COSV52886606; called by muse, mutect2, varscan2
- MYBPC2 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV63100487; called by muse, mutect2, varscan2
- OR51M1 | c.109C>T p.H37Y | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1188881153, COSV60785642; called by muse, mutect2
- PRDM9 | c.1071T>A p.Y357* | Nonsense Mutation (SNP) | VAF 12/158 reads (8%) | catalogued as COSV57014329; called by muse, mutect2
- SPR | c.410G>A p.S137N | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.108); catalogued as COSV52298721; called by muse, mutect2, varscan2
- SRRM2 | c.369G>T p.Q123H | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as COSV57081396; called by muse, mutect2, varscan2
- GRIA4 | c.1740C>T p.D580= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs542853979, COSV56922996; called by muse, mutect2, varscan2
